Surgical pathology report (de-identified scan), TCGA case TCGA-5R-AA1D, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Proteogenex, Inc, specimen TCGA-5R-AA1D-01A (Primary Tumor).

[page 1 of 2]
ICD O.3
Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
9/21/27/14 JDS

Age/Sex: years / F

Date:

Procedure: Right hemihepatectomy, cholecystectomy

Preoperative diagnosis: CARCINOMA OF THE LIVER

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LIVER, RIGHT LOBE 2. GALLBLADDER 3. RETROPANCREATIC LYMPH NODES 4. COMMON HEPATIC LYMPH NODES

Diagnosis:

1. LIVER, RIGHT LOBE:

- Poorly differentiated hepatocellular carcinoma
- Vascular invasion is present
- Satellite
- Metavir fibrosis score 0, Knodell histological activity index score 0, Ishak fibrosis score 0
- Resection margin is free of tumor

2. GALLBLADDER:

- Autolysis

3. RETROPANCREATIC LYMPH NODES:

- All (two) lymph nodes are negative for metastatic carcinoma

4. COMMON HEPATIC LYMPH NODES:

- All (seven) lymph nodes are negative for metastatic carcinoma

Gross description:

1. LIVER, RIGHT LOBE:

Received fresh, is a right lobe of the liver 19.0 x 15.0 x 6.0 cm in dimensions. At a distance of 2.0 cm from the resection margin the well-circumscribed firm lobulated green-brown tumor 11.0 x 6.5 x 8.0 cm in dimensions is present. Near the tumor there is a satellite 2.0 cm in diameter. The remaining hepatic tissue is flabby and reddish-brown.

2. GALLBLADDER:

Received fresh, is a gallbladder 6.5 x 2.0 x 1.5 cm in dimensions with a smooth greenish serosa and a plush greenish mucosa. The gallbladder contains bile.

3. RETROPANCREATIC LYMPH NODES:

[page 2 of 2]
Received fresh, is a portion of adipose tissue with two lymph nodes to 2.5 cm in greatest dimension.

4. COMMON HEPATIC LYMPH NODES:

Received fresh, is a portion of adipose tissue with seven lymph nodes ranging from 0.5 to 1.5 cm in greatest dimension.

Source: NCI Genomic Data Commons file 3adb3e87-c334-4f79-92f7-63ec8a7ea73c (TCGA-5R-AA1D.59A41C0E-AEC6-49E3-BB91-ECFC1F7C4C80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).